Gene-level copy-number profile of tumor specimen TCGA-AA-A00Z-01A from TCGA case TCGA-AA-A00Z, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.8 years (25,872 days).
Specimen TCGA-AA-A00Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.de521140-daca-496c-a671-5dbaf099956a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c398096a-0dbf-46cf-a199-ccf244f7d793

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 5,607; copy number 2: 46,310; copy number 3: 4,627; copy number 4: 2,727; copy number 5: 234; copy number 6: 71; copy number 7: 34; copy number 19: 11; copy number 21: 74; copy number 23: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A00Z-01A-01D-A003-01): tumor purity 0.63, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:73,952,940–73,954,014, 1 gene: AC093283.1.
- chr10:44,712–1,132,384, 22 genes (within-gene range 0–1): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37.
- chr18:79,340,258–80,247,514, 32 genes: AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 448 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 21 (within-gene range 2–21): AC244205.1.
- chr2:88,857,161–89,196,829, 33 genes, copy number 21: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr5:127,703,389–128,083,172, 4 genes, copy number 5 (within-gene range 2–5): CCDC192, CUL1P1, AC068658.1, LINC01184.
- chr13:49,956,670–51,024,120, 24 genes, copy number 5 (within-gene range 2–5): DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B.
- chr19:10,391,133–11,686,569, 71 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:27,638,483–35,267,964, 197 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:22,038,643–22,215,270, 1 gene, copy number 19 (within-gene range 2–21): IGLV10-54.
- chr22:22,046,430–22,906,803, 117 genes, copy number 5–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
